Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A2P2, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A2P2-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Consultation Report

Patient
Name:
MRN:
DOB:
Gender: M
HCN:
Ordering
MD:
Copy To:

Service:
Visit #:
Location:
Facility:

Accession #:
Collected:

Case is (Single):		

Specimen(s) Received

1. Thyroid: Total Thyroid, long stitch-right superior, short stitch-left superior, double long stitch-central neck

Diagnosis

Multifocal papillary carcinoma, dominant 5.0 cm, mixed follicular, solid and trabecular patterns, right; follicular adenoma 1.0cm with degeneration and cytologic atypia, left: Thyroid

No pathological diagnosis: Lymph nodes, 5

- Total thyroidectomy specimen. See Comment.

Comment

The dominant tumor is a 5.0 cm papillary carcinoma with mixed architectural patterns including follicular, solid and trabecular. Tumor is seen in vascular spaces around this tumor but there is no associated fibrin reaction. These findings are highly suspicious for vascular invasion, but not diagnostic of it. The 0.5cm papillary microcarcinoma in the left lobe shows psammoma body formation and is likely responsible for a region of psammomatous dissemination of thyroid tumor seen in the left lobe. Some psammoma bodies are seen in lymphatic spaces in the left lobe. However, all lymph nodes examined are negative for carcinoma.

Synoptic Data

Procedure:	Total thyroidectomy
Received:	Fresh
Specimen Integrity:	Intact
Specimen Size:	Right lobe: 5.5 cm 4.5 cm 2.6 cm Left lobe: 5.7 cm 3.1 cm 0.9 cm Isthmus +/- pyramidal lobe:

1CD-0-3
carcinoma, papillary. follicular
variant 8340/3
Site: thyroid, NOS C73.9
hw
8/24/11

[page 2 of 3]
	3.2 cm	
	2.7 cm	
	0.8 cm	
Specimen Weight:	56.9 g	
Tumor Focality:	Multifocal, bilateral	
----- DOMINANT TUMOR -----		
Tumor Laterality:	Right lobe	
Tumor Size:	Greatest dimension: 5.0cm	
	Additional dimension: 4.5 cm	
	Additional dimension: 2.5 cm	
Histologic Type:	Papillary carcinoma, follicular variant	
	Papillary carcinoma, solid variant	
	Papillary carcinoma, other variant: trabecular	per TSS, follicular variant = 100%
	Follicular architecture	
	Solid architecture	
	Other architecture: trabecular	
	Classical cytomorphology	
Histologic Grade:	Not applicable	
Margins:	Margins uninvolved by carcinoma	
Tumor Capsule:	Totally encapsulated	
Tumor Capsular Invasion:	Present, extent minimal	
Lymph-Vascular Invasion:	Indeterminate	
Perineural Invasion:	Not identified	
Extrathyroidal Extension:	Not identified	
----- SECOND TUMOR -----		
Tumor Laterality:	Left lobe	
Tumor Size:	Greatest dimension: 0.5cm	
Histologic Type:	Papillary carcinoma, classical (usual)	
	Papillary carcinoma, microcarcinoma (occult, small or microscopic) variant	
	Classical (papillary) architecture	
	Classical cytomorphology	
Histologic Grade:	Not applicable	
Margins:	Margins uninvolved by carcinoma	
Tumor Capsule:	Partially encapsulated	
Tumor Capsular Invasion:	Present, extent widely invasive	
Lymph-Vascular Invasion:	Indeterminate	
Perineural Invasion:	Not identified	
Extrathyroidal Extension:	Not identified	
TNM Descriptors:	m (multiple primary tumors)	
Primary Tumor (pT):	pT3: Tumor more than 4 cm, limited to thyroid or with minimal extrathyroidal extension (eg, extension to sternothyroid muscle or perithyroid soft tissues)	
Regional Lymph Nodes (pN):	pN0: No regional lymph node metastasis	
	Number of regional lymph nodes examined: 5	
	Number of regional lymph nodes involved: 0	
Distant Metastasis (pM):	Not applicable	
Additional Pathologic Findings:	Adenoma	
	Other: Multiple additional papillary microcarcinomas are identified in the left lobe (0.1, 0.1, and 0.1cm).	

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

[page 3 of 3]
verified by:

Electronically

Gross Description

The specimen labeled with the patient's name and as "total thyroid, long stitch-right superior" consists of a thyroid gland that is oriented with sutures and weighs 56.9 g. The right lobe measures 5.5 cm SI x 4.5 cm ML x 2.6 cm AP, the left lobe measures 5.7 cm SI x 3.1 cm ML x 0.9 cm AP and the isthmus measures 2.7 cm SI x 3.2 cm ML x 0.8 cm AP. There is a piece of soft tissue on the inferior left lobe that measures 4.0 cm SI x 1.3 cm ML x 0.9 cm AP. The external surfaces have fibrous adhesions. No parathyroid glands and 3 possible lymph nodes measuring from 0.1 to 0.5 cm in greatest dimension are identified grossly. The external surface is painted with Silver nitrate. The right lobe contains a tan-brown well delineated nodule that measures 5.0 cm SI x 4.5 cm ML x 2.5 cm AP. The left lobe contains a tan-brown well delineated nodule that measures 0.9 cm SI x 1.0 cm ML 0.7 cm AP. The remainder of the thyroid tissue is grossly unremarkable. One piece of tumor and two pieces of normal from the left lobe and multiple pieces of tumor from the right lobe are stored frozen. The remainder of the specimen is submitted as follows:

1A-I	right lobe, superior to inferior (representative sections)
	1C-D, 1H-I: one piece bisected in each set of blocks
1J-P	isthmus
1Q-AB	left lobe, superior to inferior
1AC	three possible lymph nodes

Source: NCI Genomic Data Commons file e1d5ced2-4239-423f-800d-60810bfee150 (TCGA-EM-A2P2.7AEAFE55-1489-4795-B602-79587086D85B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).